Somatic mutation profile of tumor specimen C3L-01864-02 (aliquot CPT0092860009) from CPTAC case C3L-01864, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 81.0 years (29,568 days).
Specimen C3L-01864-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e5ba28b-4d41-4502-a072-778ffdbe625d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01864-31 (Blood Derived Normal), aliquot CPT0093840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87cd3274-e074-4a35-b335-e5358dfa69bf

The open-access MAF lists 1,035 somatic variants for this specimen: 705 protein-altering or splice-affecting, 192 silent, 138 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 456, Silent 192, Frame Shift Del 151, Intron 73, Frame Shift Ins 40, Nonsense Mutation 31, 3'UTR 27, RNA 17, Splice Site 12, 5'Flank 11, Splice Region 8, 5'UTR 8.

Variants (750 of 1,035; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADVL | c.1316del p.G439Vfs*5 | Frame Shift Del (DEL) | VAF 238/609 reads (39%) | catalogued as rs748077880; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACTA1 | c.803T>C p.F268S | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.341); catalogued as rs1558081605; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP1A2 | c.1882G>A p.V628M | Missense Mutation (SNP) | VAF 138/731 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs1553245659, CM061643, COSV63402368; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 27/77 reads (35%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 164/343 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 51/128 reads (40%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NCSTN | c.17del p.G6Vfs*22 | Frame Shift Del (DEL) | VAF 78/292 reads (27%) | catalogued as rs1266104510; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 59/155 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PKD1 | c.1723-2A>G p.X575_splice | Splice Site (SNP) | VAF 108/328 reads (33%) | catalogued as rs1567214052, CS1210815; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABAT | c.668-2A>G p.X223_splice | Splice Site (SNP) | VAF 226/534 reads (42%) | catalogued as rs368460023; called by muse, mutect2, varscan2
- ABCA12 | c.4074A>C p.K1358N (on ENST00000272895 / NM_173076.3; = p.K1040N on NM_015657.3) | Missense Mutation (SNP) | VAF 21/434 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV55959887; called by muse, mutect2
- ABCA3 | c.1087A>G p.M363V | Missense Mutation (SNP) | VAF 173/414 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV100068374, COSV57053882; called by muse, mutect2, varscan2
- ABCC5 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs772502692, COSV55593298; called by muse, mutect2, varscan2
- ABCC8 | c.3788C>T p.A1263V | Missense Mutation (SNP) | VAF 196/464 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs772094360, BM1475244; called by muse, mutect2, varscan2
- ACAT2 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777914986, COSV58459779; called by muse, mutect2, varscan2
- ACTL6B | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); catalogued as rs1427125523; called by muse, mutect2
- ACTN2 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 226/807 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs780431842; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM15 | c.2006G>A p.S669N | Missense Mutation (SNP) | VAF 103/289 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.263); catalogued as rs770626276, COSV55130585; called by muse, mutect2, varscan2
- ADAMTS8 | c.25del p.R9Gfs*67 | Frame Shift Del (DEL) | VAF 28/60 reads (47%) | catalogued as rs1256160738; called by mutect2, pindel, varscan2
- ADCY7 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 82/147 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1443297102, COSV99575693; called by muse, mutect2, varscan2
- AGBL3 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 44/108 reads (41%) | catalogued as rs1441343785, COSV51948936, COSV51954450; called by muse, mutect2, varscan2
- AGRN | c.2630G>A p.C877Y | Missense Mutation (SNP) | VAF 146/323 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65072697; called by muse, mutect2, varscan2
- AGRN | c.3067C>T p.R1023* | Nonsense Mutation (SNP) | VAF 124/271 reads (46%) | catalogued as rs769541558; called by muse, mutect2, varscan2
- AHDC1 | c.3289G>A p.E1097K | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs762289372; called by muse, varscan2
- AKAP17A | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371594911, COSV58308776; called by muse, mutect2, varscan2
- ALDOA | c.297G>T p.Q99H (on ENST00000642816 / NM_001243177.4; = p.Q45H on NM_184041.5) | Missense Mutation (SNP) | VAF 214/564 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs1438920677; called by muse, mutect2, varscan2
- ALG10B | c.886del p.S296Hfs*23 | Frame Shift Del (DEL) | VAF 108/353 reads (31%) | catalogued as rs1397842268; called by mutect2, pindel, varscan2
- ALK | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 169/440 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); catalogued as rs1229550831, COSV66568652; called by muse, mutect2, varscan2
- ALOXE3 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 287/695 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs755241389; called by muse, mutect2, varscan2
- ALPP | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1377839356, COSV101235199; called by muse, mutect2, varscan2
- AMPH | c.344A>C p.D115A | Missense Mutation (SNP) | VAF 95/258 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100341843; called by muse, mutect2, varscan2
- ANKRD6 | c.1240T>C p.C414R | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470554135; called by muse, mutect2, varscan2
- ANTKMT | c.235del p.T79Rfs*28 | Frame Shift Del (DEL) | VAF 146/374 reads (39%) | catalogued as rs1162909078; called by mutect2, pindel, varscan2
- APBA1 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 15/231 reads (6%) | catalogued as COSV55222846; called by muse, mutect2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 98/218 reads (45%) | catalogued as rs3215969; called by mutect2, varscan2
- ARHGAP11A | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs143960378, COSV64381612; called by muse, mutect2, varscan2
- ARHGAP11A | c.1756G>A p.G586R | Missense Mutation (SNP) | VAF 110/240 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.894); catalogued as rs746678098; called by muse, mutect2, varscan2
- ARHGAP27 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 147/420 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs563835829; called by muse, mutect2, varscan2
- ARHGAP45 | c.3244G>A p.A1082T | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1485468895; called by muse, mutect2
- ARID1A | c.671del p.P224Rfs*8 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | catalogued as rs1462224784; called by mutect2, pindel, varscan2
- ARMC1 | c.402dup p.L135Sfs*19 | Frame Shift Ins (INS) | VAF 92/222 reads (41%) | catalogued as rs773038520; called by mutect2, pindel, varscan2
- ARPC5 | c.188del p.P63Lfs*9 | Frame Shift Del (DEL) | VAF 71/276 reads (26%) | catalogued as rs1558122795, COSV54172267; called by mutect2, pindel, varscan2
- ASAP2 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 117/255 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.073); catalogued as rs760855378; called by muse, mutect2, varscan2
- ASB10 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775064026, COSV51998277; called by muse, mutect2, varscan2
- ATL3 | c.1168T>A p.F390I | Missense Mutation (SNP) | VAF 102/240 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs754451134; called by muse, mutect2, varscan2
- ATM | c.8987+1G>A p.X2996_splice | Splice Site (SNP) | VAF 175/448 reads (39%) | catalogued as CS991315; called by muse, mutect2, varscan2
- BAHCC1 | c.2720G>A p.R907Q | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs782122361; called by muse, mutect2, varscan2
- BBS12 | c.2092C>G p.Q698E | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1363317599; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 96/213 reads (45%) | catalogued as rs768244116; called by mutect2, varscan2
- BHLHE22 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as rs769860258; called by muse, mutect2
- BHLHE22 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58863181; called by muse, mutect2
- BPIFB6 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 95/244 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV100848480; called by muse, mutect2, varscan2
- BRD4 | c.2728del p.Q910Kfs*39 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs868796773; called by mutect2, pindel
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | catalogued as rs746043904; called by mutect2, varscan2
- C11orf98 | c.17dup p.I8Dfs*82 (on ENST00000525675; = p.I8Dfs*91 on NM_001286086.2) | Frame Shift Ins (INS) | VAF 92/254 reads (36%) | catalogued as rs1565125738; called by mutect2, pindel, varscan2
- C17orf80 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 139/329 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs370146162; called by muse, mutect2, varscan2
- C21orf58 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as rs373462670; called by muse, varscan2
- C4orf47 | c.278del p.N93Ifs*2 | Frame Shift Del (DEL) | VAF 101/246 reads (41%) | catalogued as rs564059162; called by mutect2, varscan2
- C7 | c.67T>C p.S23P | Missense Mutation (SNP) | VAF 127/290 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV57481436; called by muse, mutect2, varscan2
- CA5B | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 114/255 reads (45%) | catalogued as COSV59418352; called by muse, mutect2, varscan2
- CABLES2 | c.656_657del p.S219Cfs*8 | Frame Shift Del (DEL) | VAF 91/303 reads (30%) | catalogued as rs1242427088; called by pindel, varscan2
- CADPS | c.83del p.P28Rfs*70 | Frame Shift Del (DEL) | VAF 71/200 reads (36%) | catalogued as COSV99340480; called by mutect2, pindel, varscan2
- CAPN2 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 91/285 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1300736855; called by muse, mutect2, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 37/91 reads (41%) | catalogued as rs770159446; called by mutect2, varscan2
- CASP5 | c.242A>G p.H81R | Missense Mutation (SNP) | VAF 127/255 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs754876585; called by muse, mutect2, varscan2
- CBLN3 | c.174del p.G61Efs*43 | Frame Shift Del (DEL) | VAF 86/210 reads (41%) | catalogued as COSV52161701; called by mutect2, pindel, varscan2
- CBX3 | c.42del p.K14Nfs*23 | Frame Shift Del (DEL) | VAF 57/158 reads (36%) | catalogued as COSV61761904; called by mutect2, pindel, varscan2
- CCDC136 | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 190/421 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs751743986, COSV52802160; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 44/88 reads (50%) | catalogued as rs535192849; called by mutect2, varscan2
- CDKN2A | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 40/512 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV58691501; called by muse, mutect2
- CELSR3 | c.7424G>A p.R2475Q | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216698308; called by muse, mutect2, varscan2
- CENPP | c.519del p.F173Lfs*46 | Frame Shift Del (DEL) | VAF 69/206 reads (33%) | catalogued as rs750494120; called by mutect2, pindel, varscan2
- CERK | c.1428dup p.K477Efs*52 | Frame Shift Ins (INS) | VAF 162/454 reads (36%) | catalogued as rs761362852; called by mutect2, varscan2
- CHD5 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 12/388 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as COSV99314849; called by muse, mutect2
- CIPC | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 122/326 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV100694435; called by muse, mutect2, varscan2
- CIT | c.4042+2T>C p.X1348_splice | Splice Site (SNP) | VAF 42/82 reads (51%) | catalogued as COSV55886930; called by muse, mutect2, varscan2
- CLASP1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs370412928; called by muse, mutect2, varscan2
- CLEC2D | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs866229731; called by muse, varscan2
- CNGA1 | c.1327del p.T443Qfs*8 | Frame Shift Del (DEL) | VAF 158/401 reads (39%) | catalogued as rs772867912; called by mutect2, pindel, varscan2
- CNGA2 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767609888, COSV61705616; called by muse, mutect2, varscan2
- CNTRL | c.6713G>A p.R2238Q | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs775971356; called by muse, mutect2, varscan2
- COL18A1 | c.4894G>A p.V1632M (on ENST00000359759 / NM_130444.3; = p.V1397M on NM_030582.4) | Missense Mutation (SNP) | VAF 138/318 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371989063; called by muse, mutect2, varscan2
- COL20A1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.566); catalogued as rs201366483; called by muse, mutect2, varscan2
- COL5A1 | c.4754G>A p.R1585Q | Missense Mutation (SNP) | VAF 156/328 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs531431738, COSV65667681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.876); catalogued as rs771886065, COSV56016775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COLQ | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 143/325 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754915644, COSV67524470; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRACDL | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.151); catalogued as COSV67407913; called by muse, mutect2, varscan2
- CRACDL | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as rs975613469; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 40/73 reads (55%) | catalogued as rs747248693; called by mutect2, varscan2
- CRYBG3 | c.6568G>A p.V2190I | Missense Mutation (SNP) | VAF 122/319 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs768639623, COSV51713764, COSV99476741; called by muse, mutect2, varscan2
- CTNND1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as rs758501334, COSV62382977; called by muse, mutect2, varscan2
- CYBRD1 | c.848G>A p.R283K | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as rs998194468; called by muse, mutect2
- DACH2 | c.1573del p.T525Pfs*33 | Frame Shift Del (DEL) | VAF 94/222 reads (42%) | catalogued as COSV100912973, COSV64169192; called by mutect2, pindel, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | catalogued as COSV99245498; called by mutect2, pindel
- DDX41 | c.*758-3C>T | Splice Region (SNP) | VAF 82/333 reads (25%) | catalogued as rs371672206; called by muse, mutect2, varscan2
- DEAF1 | c.56_82del p.V19_A27del | In Frame Del (DEL) | VAF 86/176 reads (49%) | catalogued as rs768085739; ClinVar: uncertain significance; called by mutect2, varscan2
- DHTKD1 | c.2662C>T p.R888C | Missense Mutation (SNP) | VAF 140/286 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as rs143212640; called by muse, mutect2, varscan2
- DPF3 | c.803del p.G268Afs*4 | Frame Shift Del (DEL) | VAF 91/248 reads (37%) | catalogued as rs750670452, COSV63503637; called by mutect2, pindel, varscan2
- DYNC1I1 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760252944, COSV61459085; called by muse, mutect2, varscan2
- EBF3 | c.1489G>A p.A497T (on ENST00000355311 / NM_001375392.1; = p.A488T on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/208 reads (47%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.047); catalogued as rs138447716, COSV100799028; called by muse, mutect2, varscan2
- ECSIT | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 220/526 reads (42%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs761854037, COSV52939170; called by muse, mutect2, varscan2
- EHD4 | c.1503G>T p.E501D | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV99587922; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 58/127 reads (46%) | catalogued as rs759858342; called by mutect2, pindel, varscan2
- ENPP3 | c.1733C>A p.P578H | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100718263; called by muse, varscan2
- EPAS1 | c.2482G>A p.G828R | Missense Mutation (SNP) | VAF 289/642 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs749690854; called by muse, mutect2, varscan2
- EPHB4 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as rs1453576486, COSV62269439; called by muse, mutect2, varscan2
- ETV1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 169/433 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs772105404, COSV54136587; called by muse, mutect2, varscan2
- EVPLL | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1400796383, COSV67684731; called by muse, mutect2, varscan2
- FAM135B | c.458C>G p.P153R | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50522481; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 161/405 reads (40%) | catalogued as rs768952789; called by mutect2, pindel, varscan2
- FANCA | c.643_644del p.C215Lfs*4 | Frame Shift Del (DEL) | VAF 188/541 reads (35%) | catalogued as rs1338138752; called by pindel, varscan2
- FBN2 | c.5684A>G p.E1895G | Missense Mutation (SNP) | VAF 137/351 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1417599373; called by muse, mutect2, varscan2
- FBXO34 | c.1454dup p.L485Ffs*15 | Frame Shift Ins (INS) | VAF 88/336 reads (26%) | catalogued as rs759373712; called by mutect2, varscan2
- FBXO42 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.908); catalogued as rs1385778930; called by muse, mutect2, varscan2
- FGGY | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV58036344; called by muse, mutect2, varscan2
- FMNL3 | c.1262T>C p.M421T | Missense Mutation (SNP) | VAF 108/348 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as rs971704330; called by muse, mutect2, varscan2
- FOXD4 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 229/582 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs746885586; called by muse, mutect2, varscan2
- FPGS | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.933); catalogued as rs200706232; called by muse, mutect2, varscan2
- GALP | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 91/197 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.14); catalogued as COSV61999219; called by muse, mutect2, varscan2
- GATA3 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 191/424 reads (45%) | catalogued as rs1220593366; called by muse, mutect2, varscan2
- GIPC2 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 159/398 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1421789727; called by muse, mutect2, varscan2
- GNPAT | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 206/653 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs774134716, COSV64153478; called by muse, mutect2, varscan2
- GPAT2 | c.2048G>A p.C683Y | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); catalogued as COSV100853277; called by muse, mutect2, varscan2
- GRK3 | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV100151460; called by muse, varscan2
- GTF2IRD2 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs201888085; called by mutect2, varscan2
- GUCY2F | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 95/203 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1477248854, COSV54297893; called by muse, mutect2, varscan2
- HAND2 | c.282dup p.P95Afs*248 | Frame Shift Ins (INS) | VAF 52/134 reads (39%) | catalogued as rs752622628; called by mutect2, varscan2
- HBA2 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs281864869; called by muse, mutect2, varscan2
- HDAC5 | c.2793del p.I932Lfs*14 | Frame Shift Del (DEL) | VAF 106/289 reads (37%) | catalogued as COSV52242263; called by mutect2, pindel, varscan2
- HSD3B1 | c.453G>A p.W151* | Nonsense Mutation (SNP) | VAF 171/375 reads (46%) | catalogued as rs1176201497; called by muse, mutect2, varscan2
- IGHD | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 260/595 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as rs1185079449; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 30/72 reads (42%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- IP6K1 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 101/216 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769791058; called by muse, mutect2, varscan2
- IRS4 | c.1952del p.G651Efs*23 | Frame Shift Del (DEL) | VAF 52/526 reads (10%) | catalogued as COSV64532818; called by mutect2, pindel
- ITK | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 125/307 reads (41%) | catalogued as COSV70065697; called by muse, mutect2, varscan2
- JAZF1-AS1 | n.285T>C | Splice Region (SNP) | VAF 95/196 reads (48%) | catalogued as rs1367540313; called by muse, mutect2, varscan2
- JPH2 | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 222/485 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs757549568; called by muse, mutect2, varscan2
- KATNIP | c.3086G>A p.R1029H | Missense Mutation (SNP) | VAF 135/309 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs369563369; called by muse, mutect2, varscan2
- KCNA6 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.005); catalogued as rs1421622575; called by muse, mutect2, varscan2
- KCNK10 | c.98del p.P33Rfs*20 | Frame Shift Del (DEL) | VAF 26/211 reads (12%) | catalogued as rs1566707481, COSV56642936; called by mutect2, pindel, varscan2
- KCNMA1 | c.2948del p.P983Qfs*23 (on ENST00000286628 / NM_001161352.2; = p.P925Qfs*23 on NM_002247.4) | Frame Shift Del (DEL) | VAF 197/473 reads (42%) | catalogued as COSV54274373, COSV54297445; called by mutect2, pindel, varscan2
- KCNQ5 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59648855; called by muse, mutect2
- KDM5C | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 225/465 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62891685; called by muse, mutect2, varscan2
- KIAA1217 | c.2219C>T p.T740M | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); catalogued as rs771678693; called by muse, mutect2, varscan2
- KIT | c.120_123dup p.G42Sfs*15 | Frame Shift Ins (INS) | VAF 86/294 reads (29%) | catalogued as rs1161473997; called by mutect2, varscan2
- KLF2 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as rs969344834; called by muse, mutect2, varscan2
- KMT2A | c.2975C>T p.S992F | Missense Mutation (SNP) | VAF 106/221 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV63287360; called by muse, mutect2, varscan2
- KMT2B | c.6413dup p.A2139Gfs*6 | Frame Shift Ins (INS) | VAF 81/240 reads (34%) | catalogued as rs754806477; called by mutect2, pindel, varscan2
- KMT2C | c.3155A>C p.K1052T | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51494343, COSV51498282; called by muse, mutect2, varscan2
- KRT7 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 81/192 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as rs769784859; called by muse, mutect2, varscan2
- KSR2 | c.1688-1G>T p.X563_splice | Splice Site (SNP) | VAF 42/134 reads (31%) | catalogued as COSV56676052; called by muse, mutect2, varscan2
- LARP1 | c.362dup p.P122Afs*8 | Frame Shift Ins (INS) | VAF 34/113 reads (30%) | catalogued as rs760241814; called by mutect2, varscan2
- LARP1B | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs770104246, COSV52797389; called by muse, mutect2, varscan2
- LECT2 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV50847691; called by muse, mutect2, varscan2
- LGALS9 | c.577-2A>G p.X193_splice (on ENST00000395473 / NM_009587.3; = p.X161_splice on NM_002308.4) | Splice Site (SNP) | VAF 81/211 reads (38%) | catalogued as rs1482884058; called by muse, mutect2, varscan2
- LRP4 | c.5504del p.G1835Afs*9 | Frame Shift Del (DEL) | VAF 146/362 reads (40%) | catalogued as rs745628337; called by mutect2, pindel, varscan2
- LRRN4 | c.566del p.G189Afs*47 | Frame Shift Del (DEL) | VAF 38/329 reads (12%) | catalogued as rs780053537; called by mutect2, pindel, varscan2
- LRRTM3 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 122/286 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63671602; called by muse, mutect2, varscan2
- LY6K | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); catalogued as COSV99456542; called by muse, mutect2, varscan2
- MAGEB6B | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 149/321 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.925); catalogued as rs761155463; called by muse, mutect2, varscan2
- MAGED1 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs782675141, COSV58515023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP2K7 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs55800262; called by muse, mutect2, varscan2
- MAP7D1 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.182); catalogued as rs1287604936; called by muse, mutect2, varscan2
- MAPKAP1 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.876); catalogued as COSV56373283; called by muse, mutect2, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 66/179 reads (37%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs762648935; called by mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 56/122 reads (46%) | catalogued as rs746267361; called by mutect2, varscan2
- MDN1 | c.15158C>T p.A5053V | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV101021335; called by muse, mutect2, varscan2
- MED24 | c.2744G>A p.R915H | Missense Mutation (SNP) | VAF 103/249 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.401); catalogued as rs778911202; called by muse, mutect2, varscan2
- MEF2C | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs778783316; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 44/114 reads (39%) | catalogued as rs762115034; called by mutect2, varscan2
- MEX3C | c.962C>A p.P321H | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV68529591; called by muse, mutect2, varscan2
- MGAT4D | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as rs1363130649; called by muse, mutect2, varscan2
- MIB2 | c.3019C>T p.R1007C | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs776212817; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 140/295 reads (47%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MISP3 | c.1036del p.R346Afs*19 (on ENST00000269720; = p.R204Afs*19 on NM_001291291.2) | Frame Shift Del (DEL) | VAF 88/230 reads (38%) | catalogued as rs772145225; called by mutect2, pindel, varscan2
- MROH6 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 108/249 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs572665042; called by muse, mutect2, varscan2
- MSC | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 130/315 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57697375; called by muse, mutect2, varscan2
- MTA2 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 117/267 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.982); catalogued as rs775104498; called by muse, mutect2, varscan2
- MTMR6 | c.780C>G p.N260K | Missense Mutation (SNP) | VAF 88/203 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1430653449, COSV67808651; called by muse, mutect2, varscan2
- MYH1 | c.917T>C p.I306T | Missense Mutation (SNP) | VAF 135/334 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs760868551; called by muse, mutect2, varscan2
- MYO15A | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 13/408 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs928809543, COSV52760561; called by muse, mutect2
- MYO18B | c.3761G>A p.R1254H | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs774090650, COSV59124937, COSV59152211; called by muse, mutect2
- MYO18B | c.6235G>A p.D2079N | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs762351541, COSV100125041; called by muse, mutect2, varscan2
- MZF1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); catalogued as rs773571499, COSV53041845; called by muse, mutect2
- NAGK | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 84/175 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.476); catalogued as rs757025522; called by muse, mutect2, varscan2
- NAP1L1 | c.429+7A>G | Splice Region (SNP) | VAF 93/198 reads (47%) | catalogued as rs772410442; called by muse, mutect2, varscan2
- NCOR1 | c.2481G>T p.R827S | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99248342; called by muse, mutect2, varscan2
- NKAPL | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 28/291 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs756166058, COSV59197490; called by muse, mutect2
- NLRC4 | c.328C>A p.H110N | Missense Mutation (SNP) | VAF 69/132 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1426980819, COSV61593849; called by muse, mutect2, varscan2
- NLRC5 | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 111/266 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs775155889, COSV52663969, COSV99347127; called by muse, mutect2, varscan2
- NLRP12 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 244/597 reads (41%) | SIFT tolerated (0.94); PolyPhen benign (0.017); catalogued as rs1319286947, COSV60746443; called by muse, mutect2, varscan2
- NPR2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 248/608 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.109); catalogued as COSV100709276; called by muse, mutect2, varscan2
- NRXN1 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.89); catalogued as rs761279630, COSV58450781; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP153 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.828); catalogued as rs1302077414; called by muse, mutect2, varscan2
- NYX | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 193/443 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs62637036, CM003281; ClinVar: not provided; called by muse, mutect2, varscan2
- OBSCN | c.21278dup p.L7094Ifs*4 | Frame Shift Ins (INS) | VAF 124/441 reads (28%) | catalogued as rs1271409881; called by mutect2, pindel, varscan2
- OR10W1 | c.875T>C p.V292A | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1333338839, COSV67720728; called by muse, mutect2, varscan2
- PAMR1 | c.302dup p.T102Yfs*4 | Frame Shift Ins (INS) | VAF 99/243 reads (41%) | catalogued as rs751755759; called by mutect2, varscan2
- PAX5 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100814448; called by muse, mutect2
- PBXIP1 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs994613564; called by muse, mutect2, varscan2
- PCDHB2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV52030565; called by muse, mutect2
- PCDHGA2 | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 157/348 reads (45%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1254925291, COSV53910552; called by muse, mutect2, varscan2
- PCDHGA6 | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 200/397 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV53993090; called by muse, mutect2, varscan2
- PCDHGB4 | c.431A>C p.E144A | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450198160; called by muse, mutect2, varscan2
- PCLO | c.15188del p.K5063Rfs*2 | Frame Shift Del (DEL) | VAF 18/147 reads (12%) | catalogued as rs1405726136; called by mutect2, varscan2
- PCNX3 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 103/244 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.422); catalogued as rs1437680375, COSV63136716; called by muse, mutect2, varscan2
- PDE12 | c.1276_1278del p.E426del | In Frame Del (DEL) | VAF 75/167 reads (45%) | catalogued as rs1324567685; called by mutect2, pindel, varscan2
- PDK2 | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs570482316, COSV99143060; called by muse, mutect2, varscan2
- PDZK1 | c.199_201del p.E67del | In Frame Del (DEL) | VAF 114/442 reads (26%) | catalogued as rs782628800; called by pindel, varscan2
- PEAR1 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 84/382 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs367928332; called by muse, mutect2, varscan2
- PELP1 | c.2392del p.L798Cfs*14 | Frame Shift Del (DEL) | VAF 72/158 reads (46%) | catalogued as rs752653446, COSV99342923; called by mutect2, varscan2
- PER1 | c.1388+1G>A p.X463_splice | Splice Site (SNP) | VAF 10/252 reads (4%) | catalogued as COSV57922525; called by muse, mutect2
- PEX14 | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 210/480 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs184807866; called by muse, mutect2, varscan2
- PGAM5 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 130/265 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs774830624; called by muse, mutect2, varscan2
- PGAP1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100698040; called by muse, mutect2, varscan2
- PHF12 | c.2011A>G p.T671A | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV99256166; called by muse, mutect2, varscan2
- PHKB | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 128/361 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574200588, COSV54534713; called by muse, mutect2, varscan2
- PI4KB | c.1514A>G p.D505G (on ENST00000368873 / NM_001369623.1; = p.D517G on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV55017289; called by muse, mutect2
- PIANP | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 202/472 reads (43%) | catalogued as rs753000806, COSV57708275; called by muse, mutect2, varscan2
- PKDCC | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs755580371; called by muse, mutect2, varscan2
- PKHD1L1 | c.7568del p.G2523Efs*6 | Frame Shift Del (DEL) | VAF 79/207 reads (38%) | catalogued as COSV101007028, COSV65749519; called by mutect2, pindel, varscan2
- PLXNA2 | c.3125G>A p.R1042Q | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as rs375491783, COSV100885086; called by muse, mutect2, varscan2
- PMS2 | c.418A>G p.N140D | Missense Mutation (SNP) | VAF 34/502 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs35911407; ClinVar: uncertain significance; called by muse, mutect2
- PNMA1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 131/295 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54094880; called by muse, mutect2, varscan2
- PNPLA2 | c.798dup p.A267Rfs*40 | Frame Shift Ins (INS) | VAF 50/292 reads (17%) | catalogued as rs1343828094; called by pindel, varscan2
- PNPLA6 | c.2695C>T p.R899C (on ENST00000414982 / NM_001166111.2; = p.R851C on NM_006702.5) | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1198393604, COSV104378943; called by muse, mutect2, varscan2
- POC5 | c.1466G>A p.R489Q (on ENST00000428202 / NM_001099271.2; = p.R464Q on NM_152408.2) | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs751771115, COSV66842429; called by muse, mutect2, varscan2
- POLD1 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs1060501824, COSV99569785; ClinVar: uncertain significance; called by muse, mutect2
- POLG | c.2923C>T p.Q975* | Nonsense Mutation (SNP) | VAF 45/416 reads (11%) | catalogued as CM142210; called by muse, mutect2, varscan2
- POM121C | c.1448G>A p.R483Q (on ENST00000607367; = p.R241Q on NM_001099415.3) | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.889); catalogued as rs781793911; called by muse, mutect2, varscan2
- POP5 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 161/336 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs1303914799; called by muse, mutect2, varscan2
- POU1F1 | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs1289773332; called by muse, mutect2, varscan2
- PPAT | c.482A>G p.Q161R | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs781673559, COSV104384992; called by muse, mutect2, varscan2
- PPEF2 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54425714; called by muse, mutect2, varscan2
- PPOX | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 241/872 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.152); catalogued as rs773171980, COSV57086963; called by muse, mutect2, varscan2
- PPP2R2D | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 121/245 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV101409032; called by muse, mutect2, varscan2
- PRAMEF6 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 280/732 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.22); catalogued as rs563629663, COSV61910081, COSV61910654; called by muse, mutect2, varscan2
- PREX2 | c.2987C>T p.A996V | Missense Mutation (SNP) | VAF 110/238 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs779206847; called by muse, mutect2, varscan2
- PRKDC | c.10814dup p.N3605Kfs*3 | Frame Shift Ins (INS) | VAF 34/141 reads (24%) | catalogued as rs1284489077; called by mutect2, varscan2
- PRM1 | c.128G>T p.R43M | Missense Mutation (SNP) | VAF 270/668 reads (40%) | PolyPhen possibly damaging (0.819); catalogued as rs752775594; called by muse, mutect2
- PROCR | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 138/394 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1452074807; called by muse, mutect2, varscan2
- PROSER1 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs749327970; called by muse, mutect2, varscan2
- PRR36 | c.3194C>A p.P1065H | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV73401694; called by muse, mutect2, varscan2
- PSMC6 | c.546A>C p.K182N (on ENST00000612399; = p.K168N on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71628479; called by muse, mutect2, varscan2
- PTPRA | c.1990_1992del p.K664del | In Frame Del (DEL) | VAF 77/233 reads (33%) | catalogued as rs763893722; called by pindel, varscan2
- RAB27A | c.148del p.R50Efs*35 | Frame Shift Del (DEL) | VAF 124/328 reads (38%) | catalogued as CD128375; called by mutect2, pindel, varscan2
- RAB3GAP1 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs765814163; called by muse, mutect2, varscan2
- RALGDS | c.1486C>A p.R496S | Missense Mutation (SNP) | VAF 50/491 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100924557; called by muse, mutect2, varscan2
- RBBP8 | c.1453T>C p.C485R | Missense Mutation (SNP) | VAF 268/564 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs144267335; called by muse, mutect2, varscan2
- REXO1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 137/306 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs751664572, COSV50082939; called by muse, mutect2, varscan2
- RP1L1 | c.851del p.P284Rfs*26 | Frame Shift Del (DEL) | VAF 18/186 reads (10%) | catalogued as rs757272743; called by mutect2, pindel
- RPN1 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1423535502; called by muse, mutect2, varscan2
- RTL3 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 39/78 reads (50%) | catalogued as COSV58185843; called by muse, mutect2, varscan2
- RTP5 | c.674del p.P225Lfs*8 | Frame Shift Del (DEL) | VAF 39/129 reads (30%) | catalogued as rs35989328, COSV100574622; called by mutect2, pindel, varscan2
- RUNX2 | c.1283G>A p.G428D (on ENST00000371438; = p.G406D on NM_001015051.3) | Missense Mutation (SNP) | VAF 31/774 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100767023; called by muse, mutect2
- S1PR1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 111/286 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59514381; called by muse, mutect2, varscan2
- SALL3 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 69/134 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1261571908; called by muse, mutect2, varscan2
- SALL3 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs765822599, COSV73305760; called by muse, mutect2, varscan2
- SAMD4A | c.72dup p.A25Cfs*45 | Frame Shift Ins (INS) | VAF 35/294 reads (12%) | catalogued as rs1325885783; called by mutect2, pindel, varscan2
- SCMH1 | c.428C>T p.T143M (on ENST00000326197 / NM_001031694.2; = p.T96M on NM_012236.4) | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775677371, COSV58231930; called by muse, mutect2, varscan2
- SEMA6A | c.2637del p.V881Ffs*20 | Frame Shift Del (DEL) | VAF 127/294 reads (43%) | catalogued as rs749631581, COSV56712590; called by mutect2, pindel, varscan2
- SEMA6C | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 97/311 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1360730118, COSV59001171; called by muse, mutect2, varscan2
- SEPTIN9 | c.1205G>A p.R402H (on ENST00000427177 / NM_001113491.2; = p.R384H on NM_006640.4) | Missense Mutation (SNP) | VAF 150/361 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.094); catalogued as rs756011135, COSV61202481; called by muse, mutect2, varscan2
- SERPINA5 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.073); catalogued as rs1041076479; called by muse, mutect2, varscan2
- SERTAD2 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 203/480 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs755073979, COSV100512047; called by muse, mutect2, varscan2
- SETBP1 | c.1799C>T p.T600M | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201997891, COSV56322690; called by muse, mutect2
- SETD1A | c.2114G>C p.G705A | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as rs752926780, COSV99352440; called by muse, mutect2, varscan2
- SETD7 | c.1026dup p.G343Rfs*6 | Frame Shift Ins (INS) | VAF 70/186 reads (38%) | catalogued as rs35259575; called by mutect2, varscan2
- SH2B2 | c.1877del p.P626Rfs*65 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs1364524355; called by mutect2, varscan2
- SH3TC2 | c.1408A>G p.I470V | Missense Mutation (SNP) | VAF 204/485 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs779447016; called by muse, mutect2, varscan2
- SHISA6 | c.1073G>A p.R358Q (on ENST00000409168 / NM_001173461.1; = p.R409Q on NM_207386.4) | Missense Mutation (SNP) | VAF 102/264 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.669); catalogued as rs199505983, COSV69389158; called by muse, mutect2, varscan2
- SIGLEC6 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.657); catalogued as rs1442803272, COSV58433382; called by muse, mutect2, varscan2
- SLC10A6 | c.326del p.G109Afs*21 | Frame Shift Del (DEL) | VAF 52/130 reads (40%) | catalogued as rs753933531, COSV56721805; called by mutect2, pindel, varscan2
- SLC12A6 | c.617del p.L206Yfs*28 (on ENST00000354181 / NM_001365088.1; = p.L155Yfs*28 on NM_005135.2) | Frame Shift Del (DEL) | VAF 164/430 reads (38%) | catalogued as rs916571899; called by mutect2, varscan2
- SLC14A2 | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs776377373, COSV99675635; called by muse, mutect2, varscan2
- SLC25A28 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as rs200683343; called by muse, mutect2
- SLC2A5 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 108/182 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV66237322; called by muse, mutect2, varscan2
- SLC35F3 | c.131G>T p.G44V (on ENST00000366617 / NM_001300845.1; = p.G113V on NM_173508.4) | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.647); catalogued as COSV64019372; called by muse, mutect2, varscan2
- SLC45A3 | c.570del p.Y191Tfs*21 | Frame Shift Del (DEL) | VAF 179/590 reads (30%) | catalogued as COSV65654944; called by mutect2, pindel, varscan2
- SLC52A1 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54692700; called by muse, mutect2
- SLC6A3 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 270/640 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as rs779887018, COSV54361472, COSV99070751; called by muse, mutect2, varscan2
- SLC7A1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 101/242 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV66329893; called by muse, mutect2, varscan2
- SMARCAL1 | c.2247C>T p.H749= | Splice Region (SNP) | VAF 87/197 reads (44%) | catalogued as rs775975242; ClinVar: likely benign; called by muse, mutect2, varscan2
- SNX32 | c.344_345del p.E115Vfs*17 | Frame Shift Del (DEL) | VAF 152/466 reads (33%) | catalogued as rs1424854884; called by pindel, varscan2
- SPAG17 | c.282del p.K94Nfs*3 | Frame Shift Del (DEL) | VAF 64/202 reads (32%) | catalogued as rs771461785; called by mutect2, pindel, varscan2
- SPAG5 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs376805963; called by muse, mutect2, varscan2
- SPIDR | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs782769770; called by muse, mutect2, varscan2
- SPTAN1 | c.3068A>G p.K1023R | Missense Mutation (SNP) | VAF 188/441 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.899); catalogued as rs758733662; called by muse, mutect2, varscan2
- SRPX2 | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 275/611 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1199709114, COSV65933340; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SSC5D | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as rs1016359398; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 56/127 reads (44%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAC | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 48/440 reads (11%) | catalogued as rs1048947611; called by muse, mutect2, varscan2
- STRN3 | c.1796del p.N599Ifs*42 (on ENST00000357479 / NM_001083893.2; = p.N515Ifs*42 on NM_014574.4) | Frame Shift Del (DEL) | VAF 96/263 reads (37%) | catalogued as COSV62579233; called by mutect2, pindel, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 54/159 reads (34%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYF2 | c.11T>C p.I4T | Missense Mutation (SNP) | VAF 113/294 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs749137675; called by muse, mutect2, varscan2
- SZRD1 | c.78dup p.L27Tfs*25 | Frame Shift Ins (INS) | VAF 54/186 reads (29%) | catalogued as rs1363478684; called by mutect2, varscan2
- TAF1D | c.281del p.K94Rfs*26 | Frame Shift Del (DEL) | VAF 83/206 reads (40%) | catalogued as rs746556335; called by mutect2, varscan2
- TANGO6 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 45/552 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs776619779; called by muse, mutect2
- TASOR | c.2111T>C p.M704T (on ENST00000355628 / NM_001365636.2; = p.M308T on NM_015224.3) | Missense Mutation (SNP) | VAF 107/250 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs759399275; called by muse, mutect2, varscan2
- TBC1D10B | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs750686538, COSV99977262; called by muse, mutect2, varscan2
- TBC1D10C | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 109/286 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as rs990186898, COSV56705259; called by muse, mutect2, varscan2
- TBC1D9B | c.865T>C p.C289R | Missense Mutation (SNP) | VAF 119/286 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1322825223; called by muse, mutect2, varscan2
- TCP1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 136/344 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as rs765156642; called by muse, mutect2, varscan2
- TECRL | c.443del p.L148Wfs*9 | Frame Shift Del (DEL) | VAF 78/191 reads (41%) | catalogued as rs751039402; called by mutect2, varscan2
- TEX13C | c.1040C>A p.T347K | Missense Mutation (SNP) | VAF 182/416 reads (44%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.92); catalogued as COSV53563782; called by muse, mutect2, varscan2
- TIGD4 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 92/197 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs200647678; called by muse, mutect2, varscan2
- TMCC2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 154/514 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); catalogued as rs779837835; called by muse, mutect2, varscan2
- TMTC1 | c.1691del p.K564Rfs*8 (on ENST00000539277 / NM_001193451.2; = p.K456Rfs*8 on NM_175861.3) | Frame Shift Del (DEL) | VAF 109/329 reads (33%) | catalogued as COSV55479839; called by mutect2, pindel, varscan2
- TRIM17 | c.821del p.P274Qfs*17 | Frame Shift Del (DEL) | VAF 117/388 reads (30%) | catalogued as rs758372115; called by mutect2, pindel, varscan2
- TRIO | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 122/285 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs753722635; called by muse, mutect2, varscan2
- TSPAN9 | c.368T>C p.L123P | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV50723666; called by muse, mutect2
- TSPOAP1 | c.4894G>T p.A1632S | Missense Mutation (SNP) | VAF 119/306 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52120183; called by muse, mutect2, varscan2
- TTN | c.77850G>T p.W25950C (on ENST00000591111; = p.W18526C on NM_003319.4) | Missense Mutation (SNP) | VAF 44/565 reads (8%) | PolyPhen probably damaging (0.999); catalogued as COSV60006180; called by muse, mutect2
- TULP1 | c.1497C>T p.P499= | Splice Region (SNP) | VAF 117/254 reads (46%) | catalogued as rs754696404; called by muse, mutect2, varscan2
- UBA6 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100451653; called by muse, mutect2, varscan2
- UBE2O | c.3830G>A p.R1277Q | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.05); catalogued as rs371550905; called by muse, mutect2, varscan2
- UMODL1 | c.2179C>A p.L727I (on ENST00000408910 / NM_001004416.2; = p.L855I on NM_173568.3) | Missense Mutation (SNP) | VAF 111/277 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV68576178; called by muse, mutect2, varscan2
- UNC13B | c.3268C>T p.R1090* | Nonsense Mutation (SNP) | VAF 25/326 reads (8%) | catalogued as rs756943841, COSV65934103; called by muse, mutect2
- UNC79 | c.6273del p.N2092Tfs*21 (on ENST00000393151 / NM_001346218.2; = p.N1915Tfs*21 on NM_020818.5) | Frame Shift Del (DEL) | VAF 84/195 reads (43%) | catalogued as COSV56400579; called by mutect2, pindel, varscan2
- UNKL | c.50dup p.Q18Afs*3 | Frame Shift Ins (INS) | VAF 18/34 reads (53%) | catalogued as rs1331866725; called by mutect2, varscan2
- USP28 | c.2282G>A p.G761D | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.158); catalogued as COSV50157446; called by muse, mutect2, varscan2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 94/290 reads (32%) | catalogued as rs773064295, COSV51967888; called by mutect2, varscan2
- WDR24 | c.323G>A p.R108H (on ENST00000248142; = p.R46H on NM_032259.4) | Missense Mutation (SNP) | VAF 232/550 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50208857; called by muse, mutect2, varscan2
- WDR55 | c.491T>C p.M164T | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.229); catalogued as rs1191740649; called by muse, mutect2, varscan2
- WDR81 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.551); catalogued as rs1439677993, COSV58486177; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 66/178 reads (37%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- ZCCHC14 | c.2324C>A p.P775H (on ENST00000268616; = p.P912H on NM_015144.3) | Missense Mutation (SNP) | VAF 140/306 reads (46%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.215); catalogued as rs958349467; called by muse, varscan2
- ZDHHC8 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs374875529; called by muse, mutect2, varscan2
- ZFHX4 | c.6170dup p.P2058Tfs*82 | Frame Shift Ins (INS) | VAF 44/132 reads (33%) | catalogued as rs778531712; called by mutect2, varscan2
- ZFHX4 | c.7735A>G p.K2579E | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs770792836; called by muse, mutect2, varscan2
- ZFYVE21 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 91/253 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs766037904, COSV53694907; called by muse, mutect2, varscan2
- ZMYM1 | c.1516dup p.T506Nfs*9 | Frame Shift Ins (INS) | VAF 66/174 reads (38%) | catalogued as rs772297962; called by mutect2, varscan2
- ZNF14 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 41/340 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs766275293, COSV59848656; called by muse, mutect2, varscan2
- ZNF141 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 131/281 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs782077517; called by muse, mutect2, varscan2
- ZNF236 | c.5323del p.E1775Sfs*19 | Frame Shift Del (DEL) | VAF 81/211 reads (38%) | catalogued as COSV53494924; called by mutect2, pindel, varscan2
- ZNF28 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 154/350 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1474078395, COSV100354702; called by muse, mutect2, varscan2
- ZNF385C | c.1235G>A p.S412N | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV56917698; called by muse, mutect2, varscan2
- ZNF425 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.401); catalogued as rs1346925170; called by muse, mutect2, varscan2
- ZNF446 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 142/370 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1233637863; called by muse, mutect2, varscan2
- ZNF462 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 142/326 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs772326829, COSV52931890; called by muse, mutect2, varscan2
- ZNF724 | c.345del p.G116Afs*22 | Frame Shift Del (DEL) | VAF 48/135 reads (36%) | catalogued as rs781412139; called by mutect2, varscan2
- ZNF780B | c.395A>G p.Q132R | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.095); catalogued as rs753338000; called by muse, mutect2, varscan2
- ZNF804B | c.1975A>G p.S659G | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV60821519; called by muse, mutect2
- ZNF83 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs566790486, COSV56529835; called by muse, mutect2, varscan2
- ZNF837 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs535622485; called by muse, mutect2, varscan2
- ZSWIM6 | c.2963C>T p.A988V | Missense Mutation (SNP) | VAF 137/287 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99405181; called by muse, mutect2, varscan2
- ABHD14A | c.133A>G p.M45V | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABL2 | c.828del p.I277Sfs*14 (on ENST00000502732 / NM_007314.4; = p.I262Sfs*14 on NM_005158.5) | Frame Shift Del (DEL) | VAF 176/586 reads (30%) | called by mutect2, pindel, varscan2
- AC068580.4 | c.268del p.Q90Sfs*43 | Frame Shift Del (DEL) | VAF 68/171 reads (40%) | called by mutect2, pindel, varscan2
- ACBD3 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 110/311 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ACIN1 | c.2903_2907del p.V968Efs*14 | Frame Shift Del (DEL) | VAF 74/167 reads (44%) | called by mutect2, pindel, varscan2
- ACO1 | c.1957A>T p.T653S | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACOT9 | c.307A>G p.K103E | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ACSM2A | c.275A>C p.Q92P (on ENST00000219054; = p.Q13P on NM_001308169.2) | Missense Mutation (SNP) | VAF 109/422 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- ACTA1 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACVR1C | c.424T>C p.S142P | Missense Mutation (SNP) | VAF 149/327 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS10 | c.3224T>C p.V1075A | Missense Mutation (SNP) | VAF 110/269 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADCK1 | c.365C>A p.A122D | Missense Mutation (SNP) | VAF 110/262 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ADK | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AFG3L2 | c.255del p.A86Lfs*99 | Frame Shift Del (DEL) | VAF 105/287 reads (37%) | called by mutect2, pindel, varscan2
- AFM | c.1437del p.F479Lfs*7 | Frame Shift Del (DEL) | VAF 109/248 reads (44%) | called by mutect2, pindel, varscan2
- AGBL2 | c.1705T>A p.Y569N | Missense Mutation (SNP) | VAF 36/360 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGRN | c.5522G>A p.C1841Y | Missense Mutation (SNP) | VAF 79/185 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP9 | c.11307del p.Q3770Sfs*7 (on ENST00000359028; = p.Q3746Sfs*7 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 144/379 reads (38%) | called by mutect2, pindel, varscan2
- AMMECR1 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.455); called by muse, varscan2
- AMN | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 105/258 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ANKDD1A | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKEF1 | c.718T>G p.Y240D | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ANKRD33B | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- AP2A1 | c.1303T>C p.Y435H | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- APOC4 | c.377A>G p.Q126R | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- APOL6 | c.827T>C p.L276S | Missense Mutation (SNP) | VAF 130/305 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARAP3 | c.4388C>A p.P1463H | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- ARFGEF1 | c.3916+2T>C p.X1306_splice | Splice Site (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.3221G>T p.R1074M | Missense Mutation (SNP) | VAF 127/318 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARHGAP31 | c.3944_3945del p.E1315Afs*19 | Frame Shift Del (DEL) | VAF 124/388 reads (32%) | called by pindel, varscan2
- ARHGEF28 | c.1050del p.K350Nfs*18 | Frame Shift Del (DEL) | VAF 86/210 reads (41%) | called by mutect2, pindel, varscan2
- ARHGEF33 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 67/190 reads (35%) | called by muse, mutect2, varscan2
- ARHGEF40 | c.4459del p.H1487Tfs*15 | Frame Shift Del (DEL) | VAF 129/297 reads (43%) | called by mutect2, pindel, varscan2
- ATP13A2 | c.775T>C p.Y259H | Missense Mutation (SNP) | VAF 170/419 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- BANF1 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 296/709 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BAZ2A | c.2647C>T p.Q883* | Nonsense Mutation (SNP) | VAF 21/161 reads (13%) | called by muse, mutect2, varscan2
- BCOR | c.4538T>C p.V1513A (on ENST00000378444 / NM_001123385.2; = p.V1479A on NM_017745.6) | Missense Mutation (SNP) | VAF 214/479 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BLVRA | c.134G>T p.R45I | Missense Mutation (SNP) | VAF 85/679 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BTG1 | c.226del p.M76Wfs*4 | Frame Shift Del (DEL) | VAF 209/513 reads (41%) | called by mutect2, pindel, varscan2
- C2orf81 | c.889del p.V297Cfs*37 | Frame Shift Del (DEL) | VAF 61/141 reads (43%) | called by mutect2, pindel, varscan2
- CABYR | c.960del p.F320Lfs*28 | Frame Shift Del (DEL) | VAF 157/372 reads (42%) | called by mutect2, pindel, varscan2
- CACNA1S | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 273/956 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CADM4 | c.1057+1G>T p.X353_splice | Splice Site (SNP) | VAF 100/207 reads (48%) | called by muse, mutect2, varscan2
- CAMK4 | c.253del p.I85Sfs*2 | Frame Shift Del (DEL) | VAF 87/209 reads (42%) | called by mutect2, pindel, varscan2
- CAPN7 | c.1745del p.G582Vfs*12 | Frame Shift Del (DEL) | VAF 20/184 reads (11%) | called by mutect2, pindel
- CASP8 | c.1419del p.K473Nfs*? (on ENST00000432109 / NM_033355.3; = p.K490Nfs*? on NM_001228.4) | Frame Shift Del (DEL) | VAF 220/582 reads (38%) | called by mutect2, pindel, varscan2
- CASQ2 | c.78dup p.T27Hfs*3 | Frame Shift Ins (INS) | VAF 153/436 reads (35%) | called by mutect2, pindel, varscan2
- CBX2 | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 164/400 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- CCDC14 | c.659del p.P220Qfs*88 (on ENST00000488653; = p.P172Qfs*88 on NM_022757.5) | Frame Shift Del (DEL) | VAF 79/198 reads (40%) | called by mutect2, pindel, varscan2
- CCDC168 | c.16028C>T p.T5343I | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CCN2 | c.886del p.H296Tfs*18 | Frame Shift Del (DEL) | VAF 218/571 reads (38%) | called by mutect2, pindel, varscan2
- CCNT2 | c.1174G>T p.G392* | Nonsense Mutation (SNP) | VAF 171/383 reads (45%) | called by muse, mutect2, varscan2
- CCR7 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2
- CCT8L2 | c.1654del p.I552Sfs*4 | Frame Shift Del (DEL) | VAF 50/122 reads (41%) | called by mutect2, varscan2
- CDC23 | c.1204T>A p.W402R | Missense Mutation (SNP) | VAF 87/228 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEL | c.1642A>G p.T548A (on ENST00000673714; = p.T545A on NM_001807.6) | Missense Mutation (SNP) | VAF 258/700 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, varscan2
- CENPC | c.2086T>C p.S696P | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2
- CERKL | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CFAP44 | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- CHD6 | c.1086del p.F362Lfs*14 | Frame Shift Del (DEL) | VAF 86/249 reads (35%) | called by mutect2, pindel, varscan2
- CHID1 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHST7 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- CLINT1 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 78/155 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLN6 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 127/419 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLSTN2 | c.1305C>A p.D435E | Missense Mutation (SNP) | VAF 140/320 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- CNN1 | c.121del p.V41* | Frame Shift Del (DEL) | VAF 47/116 reads (41%) | called by mutect2, pindel, varscan2
- CNR1 | c.766A>G p.N256D | Missense Mutation (SNP) | VAF 146/367 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- COL16A1 | c.4195C>T p.P1399S | Missense Mutation (SNP) | VAF 135/333 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CPNE7 | c.357+2T>C p.X119_splice | Splice Site (SNP) | VAF 86/184 reads (47%) | called by muse, mutect2
- CRB2 | c.1451dup p.L484Ffs*55 | Frame Shift Ins (INS) | VAF 133/393 reads (34%) | called by mutect2, pindel, varscan2
- CSE1L | c.564del p.F188Lfs*18 | Frame Shift Del (DEL) | VAF 87/219 reads (40%) | called by mutect2, pindel, varscan2
- CTBP1 | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CTNNAL1 | c.179del p.K60Sfs*12 | Frame Shift Del (DEL) | VAF 74/216 reads (34%) | called by mutect2, pindel, varscan2
- CYLD | c.2222G>A p.S741N | Missense Mutation (SNP) | VAF 140/312 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- CYP2R1 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP46A1 | c.1487del p.P496Hfs*88 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | called by mutect2, pindel, varscan2
- CYYR1 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- DEPDC1 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DHDH | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DMD | c.472A>T p.N158Y | Missense Mutation (SNP) | VAF 168/348 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMRT2 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNMBP | c.4223C>A p.P1408H | Missense Mutation (SNP) | VAF 56/492 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- DNMBP | c.2734T>C p.Y912H | Missense Mutation (SNP) | VAF 10/315 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DPT | c.395G>A p.C132Y | Missense Mutation (SNP) | VAF 25/430 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DSG1 | c.2645A>C p.E882A | Missense Mutation (SNP) | VAF 184/428 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DYSF | c.3343del p.A1115Pfs*5 | Frame Shift Del (DEL) | VAF 66/141 reads (47%) | called by mutect2, pindel, varscan2
- E2F1 | c.807_808insA p.E270Rfs*18 | Frame Shift Ins (INS) | VAF 84/239 reads (35%) | called by mutect2, pindel, varscan2
- EEA1 | c.527A>T p.K176M | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EFL1 | c.2142dup p.V715Sfs*16 | Frame Shift Ins (INS) | VAF 108/313 reads (35%) | called by mutect2, pindel, varscan2
- EIF2S3B | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 108/224 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENDOV | c.388dup p.V130Gfs*111 | Frame Shift Ins (INS) | VAF 150/391 reads (38%) | called by mutect2, pindel, varscan2
- ENOSF1 | c.274G>T p.D92Y (on ENST00000340116 / NM_001354066.2; = p.D44Y on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EPS15 | c.1256G>A p.C419Y | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EPYC | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, varscan2
- ERLIN2 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 236/557 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EYA1 | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 146/375 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- FAM155A | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 97/248 reads (39%) | called by muse, mutect2, varscan2
- FAM83A | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- FER1L5 | c.6269C>T p.A2090V (on ENST00000623019; = p.A2054V on NM_001293083.2) | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2
- FILIP1 | c.548T>A p.L183* | Nonsense Mutation (SNP) | VAF 150/344 reads (44%) | called by muse, mutect2, varscan2
- FOXA2 | c.528dup p.N177Qfs*62 (on ENST00000377115 / NM_153675.3; = p.N183Qfs*62 on NM_021784.5) | Frame Shift Ins (INS) | VAF 190/467 reads (41%) | called by mutect2, pindel, varscan2
- FOXD4L1 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 88/1154 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); called by muse, mutect2
- FOXD4L6 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 70/138 reads (51%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.76); called by mutect2, varscan2
- FOXR2 | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 180/378 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FRAS1 | c.10517A>G p.Y3506C | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FZR1 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- GABRA1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 177/420 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- GALNT6 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- GCC1 | c.2281A>T p.M761L | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- GJB1 | c.522del p.N175Tfs*21 | Frame Shift Del (DEL) | VAF 70/162 reads (43%) | called by mutect2, pindel, varscan2
- GLB1 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 182/441 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- GOLGA4 | c.3343T>G p.L1115V | Missense Mutation (SNP) | VAF 98/183 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- GOLGA4 | c.5414del p.N1805Tfs*6 | Frame Shift Del (DEL) | VAF 123/281 reads (44%) | called by mutect2, pindel, varscan2
- GP2 | c.41T>A p.L14Q | Missense Mutation (SNP) | VAF 103/243 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- GP5 | c.850del p.V284Cfs*14 | Frame Shift Del (DEL) | VAF 81/232 reads (35%) | called by mutect2, pindel, varscan2
- GPRC5C | c.364T>C p.F122L (on ENST00000652232; = p.F77L on NM_018653.4) | Missense Mutation (SNP) | VAF 203/491 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- GREB1 | c.227del p.P76Qfs*100 | Frame Shift Del (DEL) | VAF 38/93 reads (41%) | called by mutect2, pindel, varscan2
- GRK3 | c.2017G>A p.V673M | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GRM6 | c.2367G>A p.M789I | Missense Mutation (SNP) | VAF 96/226 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GTF3C3 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.351); called by muse, mutect2
- H4C3 | c.265T>C p.Y89H | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.395); called by muse, mutect2
- HDAC7 | c.1175C>T p.A392V (on ENST00000427332; = p.A431V on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HIVEP3 | c.6860G>T p.R2287M | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- HJV | c.964C>T p.P322S (on ENST00000336751 / NM_213653.4; = p.P209S on NM_145277.5) | Missense Mutation (SNP) | VAF 39/575 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HMCN1 | c.1000del p.T334Qfs*26 | Frame Shift Del (DEL) | VAF 139/595 reads (23%) | called by mutect2, pindel, varscan2
- HORMAD2 | c.407A>G p.D136G | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- HPS5 | c.1217A>G p.D406G (on ENST00000349215 / NM_181507.2; = p.D292G on NM_007216.4) | Missense Mutation (SNP) | VAF 25/314 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.17); called by muse, mutect2
- HUWE1 | c.4867C>A p.R1623S | Missense Mutation (SNP) | VAF 182/430 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- IBTK | c.877_891del p.R293_V297del | In Frame Del (DEL) | VAF 45/214 reads (21%) | called by mutect2, pindel, varscan2
- IDH3A | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- IGFN1 | c.1606G>A p.A536T (on ENST00000295591 / NM_001367841.1; = p.A2993T on NM_001164586.2) | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- IGLON5 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV3-22 | c.217T>A p.Y73N | Missense Mutation (SNP) | VAF 127/343 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- IL4I1 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 102/257 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IPO7 | c.1660_1661del p.E554Kfs*2 | Frame Shift Del (DEL) | VAF 107/287 reads (37%) | called by mutect2, pindel, varscan2
- IQCA1 | c.748A>G p.S250G | Missense Mutation (SNP) | VAF 138/306 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- IQGAP1 | c.3533C>T p.A1178V | Missense Mutation (SNP) | VAF 127/297 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- IRX3 | c.8dup p.Q5Pfs*90 | Frame Shift Ins (INS) | VAF 26/82 reads (32%) | called by mutect2, pindel
- ITGAM | c.2746T>C p.F916L (on ENST00000648685 / NM_001145808.2; = p.F915L on NM_000632.4) | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); called by muse, mutect2
- ITIH1 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ITPR1 | c.8074C>T p.Q2692* (on ENST00000354582; = p.Q2637* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- ITPR2 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KCNA5 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNC2 | c.206dup p.L70Afs*183 | Frame Shift Ins (INS) | VAF 85/239 reads (36%) | called by mutect2, pindel, varscan2
- KCNK3 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.18); called by muse, varscan2
- KDM4B | c.583C>A p.L195M | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1549L | c.2452A>G p.N818D (on ENST00000321505; = p.N1115D on NM_012194.3) | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1549L | c.5520dup p.Q1841Tfs*6 (on ENST00000321505; = p.Q2138Tfs*6 on NM_012194.3) | Frame Shift Ins (INS) | VAF 68/216 reads (31%) | called by mutect2, pindel
- KIFC1 | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLF6 | c.20G>A p.C7Y | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL33 | c.1145A>G p.Q382R | Missense Mutation (SNP) | VAF 151/389 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHL42 | c.817T>C p.S273P | Missense Mutation (SNP) | VAF 135/307 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- KMT2B | c.4235dup p.L1413Pfs*265 | Frame Shift Ins (INS) | VAF 93/220 reads (42%) | called by mutect2, pindel, varscan2
- KPNA3 | c.788_791del p.V263Gfs*6 | Frame Shift Del (DEL) | VAF 90/205 reads (44%) | called by mutect2, pindel, varscan2
- LAMA2 | c.4544G>A p.G1515D | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA3 | c.8326_8328del p.G2776del (on ENST00000313654 / NM_198129.4; = p.G1167del on NM_000227.6) | In Frame Del (DEL) | VAF 238/547 reads (44%) | called by pindel, varscan2
- LAMB3 | c.3208C>T p.Q1070* | Nonsense Mutation (SNP) | VAF 160/666 reads (24%) | called by muse, mutect2, varscan2
- LEMD3 | c.1872del p.R625Dfs*7 | Frame Shift Del (DEL) | VAF 152/383 reads (40%) | called by mutect2, pindel, varscan2
- LEPR | c.2213T>C p.V738A | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); called by muse, mutect2
- LGI2 | c.820+1G>A p.X274_splice | Splice Site (SNP) | VAF 82/157 reads (52%) | called by muse, mutect2, varscan2
- LMNB2 | c.981+2T>C p.X327_splice | Splice Site (SNP) | VAF 56/124 reads (45%) | called by muse, mutect2, varscan2
- LRP11 | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 112/255 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- LRRC4 | c.827A>C p.N276T | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LTBR | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 96/218 reads (44%) | called by muse, mutect2, varscan2
- MALRD1 | c.3439T>C p.Y1147H | Missense Mutation (SNP) | VAF 86/202 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MAP3K15 | c.2680del p.H894Tfs*10 | Frame Shift Del (DEL) | VAF 118/317 reads (37%) | called by mutect2, pindel, varscan2
- MDC1 | c.1918A>G p.I640V | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDN1 | c.12532G>A p.D4178N | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- MED14 | c.1814G>T p.G605V | Missense Mutation (SNP) | VAF 119/276 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MEF2D | c.623del p.G208Vfs*3 | Frame Shift Del (DEL) | VAF 68/234 reads (29%) | called by mutect2, pindel, varscan2
- MEIS3 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- MGA | c.3297dup p.Q1100Sfs*13 | Frame Shift Ins (INS) | VAF 176/430 reads (41%) | called by mutect2, pindel, varscan2
- MGA | c.7159G>A p.A2387T (on ENST00000219905 / NM_001164273.1; = p.A2178T on NM_001080541.2) | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MGST1 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MMP23B | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 133/424 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP28 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTBP | c.845del p.K282Rfs*22 | Frame Shift Del (DEL) | VAF 16/158 reads (10%) | called by mutect2, pindel
- MTDH | c.1432T>G p.S478A | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MTMR11 | c.263A>G p.Q88R (on ENST00000439741 / NM_001145862.2; = p.Q16R on NM_181873.3) | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.107); called by muse, mutect2
- MUC16 | c.14621G>A p.R4874K | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MYCT1 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYO7A | c.2587T>C p.Y863H | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- NAGS | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 201/469 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBEAL2 | c.1929G>T p.E643D | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBPF9 | c.358T>A p.S120T | Missense Mutation (SNP) | VAF 112/766 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NCAM2 | c.1574T>C p.V525A | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2
- NCK2 | c.994C>A p.H332N | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDUFAF6 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- NEFH | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 136/289 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- NEFH | c.1466del p.G489Vfs*32 | Frame Shift Del (DEL) | VAF 168/454 reads (37%) | called by mutect2, pindel, varscan2
- NEFM | c.1580del p.K527Rfs*192 | Frame Shift Del (DEL) | VAF 214/598 reads (36%) | called by mutect2, pindel, varscan2
- NFKB1 | c.2569dup p.T857Nfs*7 (on ENST00000394820 / NM_001382627.1; = p.T858Nfs*7 on NM_003998.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 62/180 reads (34%) | called by mutect2, pindel, varscan2
- NFKBIB | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- NOL8 | c.470del p.N157Ifs*19 | Frame Shift Del (DEL) | VAF 114/329 reads (35%) | called by mutect2, pindel, varscan2
- NR5A2 | c.1013del p.K338Sfs*2 (on ENST00000367362 / NM_205860.3; = p.K292Sfs*2 on NM_003822.5) | Frame Shift Del (DEL) | VAF 186/746 reads (25%) | called by mutect2, pindel, varscan2
- NRG3 | c.148del p.R50Gfs*53 | Frame Shift Del (DEL) | VAF 33/74 reads (45%) | called by mutect2, pindel, varscan2
- NTN1 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- NUDT4 | c.346_347del p.K116Efs*17 | Frame Shift Del (DEL) | VAF 21/204 reads (10%) | called by mutect2, pindel, varscan2
- NUTM2F | c.313G>C p.A105P | Missense Mutation (SNP) | VAF 101/314 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR1L6 | c.932C>T p.A311V (on ENST00000373684; = p.A275V on NM_001004453.2) | Missense Mutation (SNP) | VAF 81/226 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- OR2A14 | c.403A>G p.M135V | Missense Mutation (SNP) | VAF 112/229 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OR2AG2 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 154/384 reads (40%) | called by muse, mutect2, varscan2
- PARP2 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 123/296 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PARP4 | c.2216T>A p.I739N | Missense Mutation (SNP) | VAF 115/287 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- PCDHGC3 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 118/290 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PDHA1 | c.418+6C>A | Splice Region (SNP) | VAF 67/189 reads (35%) | called by muse, mutect2, varscan2
- PDZD2 | c.6719del p.P2240Hfs*14 | Frame Shift Del (DEL) | VAF 69/178 reads (39%) | called by mutect2, pindel, varscan2
- PER1 | c.2953A>G p.N985D | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2
- PHACTR4 | c.1037del p.P346Hfs*33 (on ENST00000373839 / NM_001350159.2; = p.P356Hfs*33 on NM_023923.4) | Frame Shift Del (DEL) | VAF 118/302 reads (39%) | called by mutect2, pindel, varscan2
- PHC2 | c.1579G>C p.A527P | Missense Mutation (SNP) | VAF 144/276 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PIKFYVE | c.5362G>C p.V1788L | Missense Mutation (SNP) | VAF 197/472 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCB3 | c.2752del p.R918Afs*95 | Frame Shift Del (DEL) | VAF 73/211 reads (35%) | called by mutect2, pindel, varscan2
- PLCH1 | c.184G>A p.A62T (on ENST00000340059 / NM_001130960.2; = p.A74T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, varscan2
- PMVK | c.77C>A p.T26N | Missense Mutation (SNP) | VAF 93/300 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- PNKP | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 215/458 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POPDC2 | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 27/442 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- POU2F1 | c.1405A>G p.T469A (on ENST00000541643 / NM_001365848.1; = p.T492A on NM_002697.4) | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PPCDC | c.187dup p.Q63Pfs*12 | Frame Shift Ins (INS) | VAF 116/335 reads (35%) | called by mutect2, pindel, varscan2
- PPIG | c.36del p.F12Lfs*115 | Frame Shift Del (DEL) | VAF 117/307 reads (38%) | called by mutect2, pindel, varscan2
- PPRC1 | c.3342del p.L1115Cfs*26 | Frame Shift Del (DEL) | VAF 143/489 reads (29%) | called by mutect2, pindel, varscan2
- PRDM4 | c.2202del p.K734Nfs*7 | Frame Shift Del (DEL) | VAF 144/405 reads (36%) | called by mutect2, pindel, varscan2
- PRKCA | c.227A>C p.K76T | Missense Mutation (SNP) | VAF 115/251 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- PROM1 | c.2583-3dup | Splice Region (INS) | VAF 40/156 reads (26%) | called by pindel, varscan2
- PRRT4 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 87/186 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PRSS58 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.212); called by muse, mutect2
- PSMD1 | c.372del p.K124Nfs*11 | Frame Shift Del (DEL) | VAF 66/175 reads (38%) | called by mutect2, varscan2
- PSPC1 | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PTN | c.123del p.V42* | Frame Shift Del (DEL) | VAF 40/86 reads (47%) | called by mutect2, varscan2
- PTPN4 | c.383del p.L128Cfs*22 | Frame Shift Del (DEL) | VAF 57/173 reads (33%) | called by mutect2, pindel, varscan2
- PTPRK | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PYGL | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 118/264 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- RAB3GAP2 | c.675del p.Q226Nfs*10 | Frame Shift Del (DEL) | VAF 139/486 reads (29%) | called by mutect2, pindel, varscan2
- RAMP2 | c.425del p.P142Qfs*8 | Frame Shift Del (DEL) | VAF 94/250 reads (38%) | called by mutect2, pindel, varscan2
- RASA1 | c.3013C>T p.H1005Y | Missense Mutation (SNP) | VAF 159/369 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- RBM14 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RBMXL3 | c.491G>T p.R164M | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- RCCD1 | c.1105T>C p.Y369H | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); called by muse, mutect2
- RD3L | c.12del p.F4Lfs*4 | Frame Shift Del (DEL) | VAF 57/145 reads (39%) | called by mutect2, pindel, varscan2
- RELT | c.158del p.P53Qfs*178 | Frame Shift Del (DEL) | VAF 80/229 reads (35%) | called by mutect2, pindel, varscan2
- RESF1 | c.4618G>T p.V1540F | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RFLNA | c.213del p.S72Pfs*11 | Frame Shift Del (DEL) | VAF 33/87 reads (38%) | called by mutect2, pindel, varscan2
- RHOBTB2 | c.1827dup p.G610Wfs*77 | Frame Shift Ins (INS) | VAF 77/190 reads (41%) | called by mutect2, pindel, varscan2
- RIN1 | c.111C>A p.D37E | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RNF165 | c.269T>A p.F90Y | Missense Mutation (SNP) | VAF 137/336 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RPTN | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 68/772 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2
- RYR1 | c.8710del p.L2904Cfs*24 | Frame Shift Del (DEL) | VAF 200/483 reads (41%) | called by mutect2, pindel, varscan2
- RYR2 | c.4460T>C p.M1487T | Missense Mutation (SNP) | VAF 115/438 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RYR3 | c.7537T>A p.C2513S (on ENST00000389232; = p.C2514S on NM_001036.6) | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- SAMD4A | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 171/414 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SAMD9 | c.153del p.E52Nfs*16 | Frame Shift Del (DEL) | VAF 13/131 reads (10%) | called by mutect2, pindel
- SAMSN1 | c.711G>C p.R237S | Missense Mutation (SNP) | VAF 141/353 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCART1 | c.2366G>A p.R789H | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SCNN1D | c.1487G>A p.S496N (on ENST00000338555; = p.S660N on NM_001130413.4) | Missense Mutation (SNP) | VAF 140/322 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SCX | c.476del p.P159Rfs*31 | Frame Shift Del (DEL) | VAF 153/410 reads (37%) | called by mutect2, pindel, varscan2
- SEC16B | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 77/325 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SEMA4C | c.2271del p.P759Lfs*36 | Frame Shift Del (DEL) | VAF 149/386 reads (39%) | called by mutect2, pindel, varscan2
- SEMA6C | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 357/587 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SH3PXD2A | c.2792G>T p.R931M (on ENST00000369774 / NM_001365079.1; = p.R903M on NM_014631.2) | Missense Mutation (SNP) | VAF 150/319 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.235); called by muse, mutect2
- SH3RF1 | c.2583del p.K861Nfs*37 | Frame Shift Del (DEL) | VAF 106/308 reads (34%) | called by mutect2, pindel, varscan2
- SH3RF3 | c.2140A>G p.S714G | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIPA1L3 | c.2650dup p.V884Gfs*12 | Frame Shift Ins (INS) | VAF 72/191 reads (38%) | called by mutect2, varscan2
- SLC10A4 | c.812G>T p.W271L | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.089); called by muse, varscan2
- SLC1A3 | c.968T>C p.V323A | Missense Mutation (SNP) | VAF 50/521 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.041); called by muse, mutect2
- SLC22A16 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SLC22A9 | c.1420del p.A474Qfs*6 | Frame Shift Del (DEL) | VAF 73/195 reads (37%) | called by mutect2, pindel, varscan2
- SLC25A44 | c.424A>G p.K142E | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC30A4 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- SLC44A5 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SLC8A3 | c.598C>A p.L200I | Missense Mutation (SNP) | VAF 149/364 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SLK | c.2810C>A p.P937H | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SMAP1 | c.588A>C p.K196N (on ENST00000370455 / NM_001044305.3; = p.K169N on NM_021940.5) | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- SMC1A | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 281/633 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- SMC3 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 112/264 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SMG1 | c.3939G>A p.W1313* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- SOGA1 | c.4496T>A p.V1499E | Missense Mutation (SNP) | VAF 167/387 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SP110 | c.1631del p.G544Dfs*36 | Frame Shift Del (DEL) | VAF 175/464 reads (38%) | called by mutect2, pindel, varscan2
- SP7 | c.884G>A p.S295N | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SPATA13 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 35/295 reads (12%) | called by muse, mutect2, varscan2
- SPNS1 | c.1108C>A p.L370I | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- SPPL2C | c.1307T>C p.L436P | Missense Mutation (SNP) | VAF 247/587 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SPPL3 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 169/413 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- SRCIN1 | c.2482G>T p.E828* (on ENST00000621492; = p.E794* on NM_025248.3) | Nonsense Mutation (SNP) | VAF 176/402 reads (44%) | called by muse, mutect2, varscan2
- SRRD | c.432C>A p.Y144* | Nonsense Mutation (SNP) | VAF 99/247 reads (40%) | called by muse, mutect2, varscan2
- SSH3 | c.1472C>A p.P491H | Missense Mutation (SNP) | VAF 123/284 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ST18 | c.2156del p.K719Rfs*3 | Frame Shift Del (DEL) | VAF 95/219 reads (43%) | called by mutect2, pindel, varscan2
- STARD3NL | c.158G>T p.R53M | Missense Mutation (SNP) | VAF 170/415 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAT1 | c.1701del p.K567Nfs*25 | Frame Shift Del (DEL) | VAF 188/498 reads (38%) | called by mutect2, pindel, varscan2
- STK32C | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 106/275 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- STRIP1 | c.1483_1484del p.S495Rfs*7 | Frame Shift Del (DEL) | VAF 80/267 reads (30%) | called by pindel, varscan2
- SUGP2 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 101/339 reads (30%) | called by muse, mutect2, varscan2
- SULT1A2 | c.97A>C p.S33R | Missense Mutation (SNP) | VAF 117/321 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- SUPT20HL1 | c.2609G>A p.G870E | Missense Mutation (SNP) | VAF 103/219 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SUSD4 | c.1235del p.P412Qfs*51 | Frame Shift Del (DEL) | VAF 69/247 reads (28%) | called by mutect2, pindel, varscan2
- SYK | c.1127A>G p.E376G | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D14 | c.890dup p.Q298Afs*8 | Frame Shift Ins (INS) | VAF 118/344 reads (34%) | called by mutect2, pindel, varscan2
- TBK1 | c.1189del p.I397Ffs*12 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | called by mutect2, pindel
- TCEAL3 | c.172G>T p.G58* | Nonsense Mutation (SNP) | VAF 108/235 reads (46%) | called by muse, mutect2, varscan2
- TDRD12 | c.3389C>A p.P1130H (on ENST00000444215; = p.P1135H on NM_001366102.1) | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- TDRD5 | c.1907del p.L636Cfs*16 | Frame Shift Del (DEL) | VAF 138/548 reads (25%) | called by mutect2, pindel, varscan2
- TELO2 | c.1254C>A p.H418Q | Missense Mutation (SNP) | VAF 150/322 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); called by muse, varscan2
- TEPP | c.287T>G p.L96R | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TET2 | c.5860G>A p.A1954T | Missense Mutation (SNP) | VAF 137/339 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- THEG | c.135del p.E46Nfs*71 | Frame Shift Del (DEL) | VAF 8/104 reads (8%) | called by mutect2, pindel
- THEMIS2 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TIAM1 | c.528G>A p.W176* | Nonsense Mutation (SNP) | VAF 14/370 reads (4%) | called by muse, mutect2
- TMEM140 | c.295del p.Q99Sfs*5 | Frame Shift Del (DEL) | VAF 113/284 reads (40%) | called by mutect2, pindel, varscan2
- TMEM185B | c.1014del p.P341Lfs*4 | Frame Shift Del (DEL) | VAF 52/157 reads (33%) | called by mutect2, pindel
- TMTC1 | c.763C>T p.Q255* (on ENST00000539277 / NM_001193451.2; = p.Q147* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 67/138 reads (49%) | called by muse, mutect2, varscan2
- TNFRSF6B | c.161dup p.G55Rfs*45 | Frame Shift Ins (INS) | VAF 78/202 reads (39%) | called by mutect2, pindel, varscan2
- TNRC18 | c.2345del p.G782Afs*91 | Frame Shift Del (DEL) | VAF 93/234 reads (40%) | called by mutect2, pindel, varscan2
- TNXB | c.12019dup p.R4007Pfs*2 (on ENST00000647633; = p.R3760Pfs*2 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 13/115 reads (11%) | called by mutect2, pindel
- TOP2A | c.3658A>G p.I1220V | Missense Mutation (SNP) | VAF 127/301 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPI1 | c.569-6C>T | Splice Region (SNP) | VAF 256/624 reads (41%) | called by muse, mutect2, varscan2
- TRIM56 | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.019); called by muse, varscan2
- TRIM56 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.156); called by muse, varscan2
- TRIP11 | c.1678C>T p.Q560* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | called by muse, varscan2
- TRPV5 | c.494A>G p.H165R | Missense Mutation (SNP) | VAF 114/252 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TTBK1 | c.2654G>A p.G885D | Missense Mutation (SNP) | VAF 125/278 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC21A | c.2449G>A p.V817I | Missense Mutation (SNP) | VAF 104/255 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- TTN | c.86410C>T p.P28804S (on ENST00000591111; = p.P21380S on NM_003319.4) | Missense Mutation (SNP) | VAF 148/399 reads (37%) | PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TTN | c.32768del p.K10923Rfs*104 (on ENST00000591111; = p.K9996Rfs*104 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 150/354 reads (42%) | called by mutect2, pindel, varscan2
- UBE2G2 | c.105dup p.E36* | Frame Shift Ins (INS) | VAF 101/267 reads (38%) | called by mutect2, pindel, varscan2
- ULK1 | c.2618del p.G873Afs*18 | Frame Shift Del (DEL) | VAF 29/76 reads (38%) | called by mutect2, pindel, varscan2
- UNC5D | c.1046A>G p.Q349R | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.32); called by muse, mutect2
- URB1 | c.2382G>T p.R794S | Missense Mutation (SNP) | VAF 102/218 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- USP20 | c.1094A>G p.Q365R | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.038); called by muse, mutect2
- USP36 | c.3258del p.K1086Nfs*25 | Frame Shift Del (DEL) | VAF 97/265 reads (37%) | called by mutect2, pindel, varscan2
- USP44 | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 103/273 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- VPS11 | c.702del p.K234Nfs*93 (on ENST00000620429; = p.K778Nfs*93 on NM_021729.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 106/282 reads (38%) | called by mutect2, pindel, varscan2
- VPS13C | c.3086C>A p.T1029K (on ENST00000644861 / NM_020821.3; = p.T986K on NM_017684.5) | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- WRNIP1 | c.1969dup p.V657Gfs*53 | Frame Shift Ins (INS) | VAF 114/274 reads (42%) | called by mutect2, pindel
- XRN1 | c.1073T>C p.L358P | Missense Mutation (SNP) | VAF 104/283 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- YAP1 | c.286_288del p.F96del | In Frame Del (DEL) | VAF 146/326 reads (45%) | called by pindel, varscan2
- ZBTB2 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 154/361 reads (43%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZBTB4 | c.1907G>A p.S636N | Missense Mutation (SNP) | VAF 24/335 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- ZBTB40 | c.2006T>C p.V669A | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZBTB7B | c.1174del p.H392Tfs*107 (on ENST00000292176; = p.H426Tfs*107 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 63/242 reads (26%) | called by mutect2, pindel, varscan2
- ZBTB7B | c.1394A>G p.D465G (on ENST00000292176; = p.D499G on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/441 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC2HC1B | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZC3H10 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZC3H18 | c.985del p.R329Gfs*4 | Frame Shift Del (DEL) | VAF 109/293 reads (37%) | called by mutect2, pindel, varscan2
- ZC3H6 | c.295del p.R99Efs*23 | Frame Shift Del (DEL) | VAF 23/206 reads (11%) | called by mutect2, pindel, varscan2
- ZC3H6 | c.1305dup p.P436Tfs*8 | Frame Shift Ins (INS) | VAF 67/168 reads (40%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.2379del p.S794Rfs*30 | Frame Shift Del (DEL) | VAF 184/481 reads (38%) | called by mutect2, pindel, varscan2
- ZFYVE26 | c.3746T>G p.L1249R | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZNF107 | c.458T>A p.I153N | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF19 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 44/360 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF235 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 95/260 reads (37%) | called by mutect2, pindel, varscan2
- ZNF282 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF416 | c.693del p.H232Tfs*54 | Frame Shift Del (DEL) | VAF 131/303 reads (43%) | called by mutect2, pindel, varscan2
- ZNF423 | c.1381C>A p.L461I (on ENST00000563137 / NM_001379286.1; = p.L453I on NM_015069.4) | Missense Mutation (SNP) | VAF 161/398 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ZNF442 | c.658del p.W220Gfs*34 | Frame Shift Del (DEL) | VAF 100/246 reads (41%) | called by mutect2, varscan2
- ZNF469 | c.1963del p.H655Tfs*77 | Frame Shift Del (DEL) | VAF 191/463 reads (41%) | called by mutect2, pindel, varscan2
- ZNF528 | c.306C>G p.N102K | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.111); called by muse, mutect2
- ZNF592 | c.2217del p.L740* | Frame Shift Del (DEL) | VAF 110/313 reads (35%) | called by mutect2, pindel, varscan2
- ZNF608 | c.3376G>A p.D1126N | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF654 | c.1761G>A p.M587I | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- ZNF774 | c.1301C>A p.P434H | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- AADACL4 | c.708G>A p.Q236= | Silent (SNP) | VAF 155/370 reads (42%) | catalogued as COSV66105769; called by muse, mutect2, varscan2
- ABCA2 | c.4839G>A p.G1613= (on ENST00000614293; = p.G1583= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/190 reads (37%) | called by muse, mutect2, varscan2
- ABCC10 | c.267G>A p.L89= (on ENST00000372530 / NM_001198934.2; = p.L46= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/382 reads (5%) | called by muse, mutect2
- AC126283.2 | c.1290C>T p.I430= | Silent (SNP) | VAF 43/427 reads (10%) | catalogued as rs751300644, COSV67098684; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACSBG1 | c.1665C>T p.D555= | Silent (SNP) | VAF 55/137 reads (40%) | catalogued as rs377622035; called by muse, mutect2, varscan2
- ADGRG4 | c.8028A>G p.G2676= | Silent (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- AIFM3 | c.24C>G p.P8= | Silent (SNP) | VAF 94/243 reads (39%) | called by muse, mutect2, varscan2
- ALX4 | c.1218C>A p.A406= | Silent (SNP) | VAF 95/225 reads (42%) | called by muse, mutect2, varscan2
- AMOTL2 | c.2022T>A p.A674= | Silent (SNP) | VAF 208/497 reads (42%) | called by muse, mutect2, varscan2
- AOC1 | c.931A>C p.R311= | Silent (SNP) | VAF 62/145 reads (43%) | catalogued as COSV62869857; called by muse, mutect2, varscan2
- ARHGAP30 | c.831G>A p.E277= | Silent (SNP) | VAF 85/263 reads (32%) | called by muse, mutect2, varscan2
- ARRDC1 | c.405C>A p.P135= | Silent (SNP) | VAF 112/260 reads (43%) | catalogued as COSV65060075; called by muse, mutect2, varscan2
- ARSJ | c.918C>T p.N306= | Silent (SNP) | VAF 98/201 reads (49%) | catalogued as rs924296735, COSV59538106; called by muse, mutect2, varscan2
- ASAP2 | c.2679G>A p.A893= | Silent (SNP) | VAF 73/179 reads (41%) | catalogued as rs774635664; called by muse, mutect2, varscan2
- ATP2B4 | c.996C>T p.I332= | Silent (SNP) | VAF 81/275 reads (29%) | catalogued as rs576322841; called by muse, mutect2, varscan2
- ATP5F1A | c.639C>T p.D213= | Silent (SNP) | VAF 92/209 reads (44%) | called by muse, mutect2, varscan2
- ATPAF1 | c.759G>A p.V253= (on ENST00000574428; = p.V276= on NM_022745.4) | Silent (SNP) | VAF 30/270 reads (11%) | called by muse, mutect2, varscan2
- ATXN2 | c.552G>A p.Q184= (on ENST00000550104; = p.Q24= on NM_002973.4) | Silent (SNP) | VAF 53/349 reads (15%) | catalogued as rs183549558; called by muse, varscan2
- ATXN2 | c.507G>A p.Q169= (on ENST00000550104; = p.Q9= on NM_002973.4) | Silent (SNP) | VAF 46/366 reads (13%) | catalogued as rs754985502; called by muse, varscan2
- BCOR | c.1695C>T p.G565= | Silent (SNP) | VAF 40/450 reads (9%) | called by muse, mutect2
- BPIFB1 | c.93C>T p.L31= | Silent (SNP) | VAF 26/274 reads (9%) | catalogued as rs766101557, COSV53605360; called by muse, mutect2
- BTNL9 | c.1311C>T p.R437= | Silent (SNP) | VAF 97/245 reads (40%) | catalogued as rs1205976419; called by muse, mutect2, varscan2
- C15orf39 | c.1191A>G p.T397= | Silent (SNP) | VAF 147/313 reads (47%) | called by muse, mutect2, varscan2
- C1RL | c.462G>A p.K154= | Silent (SNP) | VAF 18/238 reads (8%) | catalogued as COSV56926096; called by muse, mutect2
- C2 | c.765C>A p.L255= | Silent (SNP) | VAF 66/552 reads (12%) | called by muse, mutect2, varscan2
- C2CD2 | c.1653G>A p.P551= | Silent (SNP) | VAF 119/264 reads (45%) | catalogued as rs892436733; called by muse, mutect2, varscan2
- C6orf132 | c.939G>A p.S313= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as rs1203461331; called by muse, mutect2, varscan2
- CACNA1F | c.2538T>C p.P846= | Silent (SNP) | VAF 212/483 reads (44%) | called by muse, varscan2
- CADPS2 | c.1551A>G p.Q517= | Silent (SNP) | VAF 48/107 reads (45%) | catalogued as rs1169548413; called by muse, mutect2, varscan2
- CALCOCO1 | c.213A>G p.E71= | Silent (SNP) | VAF 144/331 reads (44%) | called by muse, mutect2, varscan2
- CCDC106 | c.774G>A p.T258= | Silent (SNP) | VAF 93/260 reads (36%) | catalogued as rs140029370; called by muse, mutect2, varscan2
- CCDC185 | c.57G>A p.P19= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs1293310255; called by muse, mutect2
- CCN3 | c.423G>A p.V141= | Silent (SNP) | VAF 121/279 reads (43%) | called by muse, mutect2, varscan2
- CDK16 | c.132T>C p.P44= | Silent (SNP) | VAF 216/515 reads (42%) | called by muse, mutect2, varscan2
- CEP126 | c.2658C>T p.F886= | Silent (SNP) | VAF 106/230 reads (46%) | catalogued as rs774738402, COSV54821415, COSV54822380; called by muse, mutect2, varscan2
- CEP192 | c.1176G>A p.Q392= | Silent (SNP) | VAF 85/217 reads (39%) | catalogued as COSV58070756; called by muse, mutect2, varscan2
- CHADL | c.336G>A p.L112= | Silent (SNP) | VAF 101/234 reads (43%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.867C>T p.D289= | Silent (SNP) | VAF 133/312 reads (43%) | catalogued as rs528700108, COSV56680363, COSV56707740; called by muse, varscan2
- COL6A6 | c.3150G>A p.P1050= | Silent (SNP) | VAF 179/361 reads (50%) | catalogued as rs557884581; called by muse, mutect2, varscan2
- CPXM1 | c.1347C>T p.D449= | Silent (SNP) | VAF 82/179 reads (46%) | catalogued as rs140373758; called by muse, mutect2, varscan2
- CSAD | c.1029C>T p.Y343= (on ENST00000444623 / NM_001244705.2; = p.Y370= on NM_015989.5) | Silent (SNP) | VAF 193/525 reads (37%) | catalogued as rs780309504, COSV57243965; called by muse, mutect2, varscan2
- CSMD3 | c.621A>G p.G207= | Silent (SNP) | VAF 46/346 reads (13%) | called by muse, mutect2, varscan2
- CTAGE15 | c.1131T>C p.N377= | Silent (SNP) | VAF 60/140 reads (43%) | called by mutect2, varscan2
- CTDSPL2 | c.1353A>G p.P451= | Silent (SNP) | VAF 100/246 reads (41%) | called by muse, mutect2, varscan2
- CYP4F3 | c.1422G>A p.A474= | Silent (SNP) | VAF 63/124 reads (51%) | catalogued as rs757825148; called by muse, mutect2, varscan2
285 further variants in this file (0 protein-altering or splice-affecting, 147 silent, 138 other) are not listed here.
